Gene-level copy-number profile of tumor specimen HCM-SANG-0265-C18-06A-01D-A80T-32 from HCMI case HCM-SANG-0265-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-SANG-0265-C18-06A-01D-A80T-32: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a43253e4-ab79-4b59-9344-8abd37ce56fe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0265-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/7972d14a-dd4b-4c74-9430-52904ef18ad7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,551; copy number 2: 20,960; copy number 3: 20,647; copy number 4: 8,233; copy number 5: 6,860; copy number 6: 115; copy number 7: 38.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,504 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–40,860,763, 705 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:53,559,214–56,116,417, 60 genes, copy number 5: AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2.
- chr7:65,647,010–67,362,950, 62 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:72,558,744–90,322,592, 288 genes, copy number 5 (broad region; genes not listed).
- chr7:90,466,424–91,210,590, 1 gene, copy number 5 (within-gene range 3–5): CDK14.
- chr7:90,590,619–153,413,985, 1,295 genes, copy number 5 (broad region; genes not listed).
- chr8:47,773,111–47,960,178, 1 gene, copy number 7 (within-gene range 3–7): PRKDC.
- chr8:47,941,426–51,321,118, 37 genes, copy number 7 (within-gene range 3–7): AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC013701.1, SNAI2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1.
- chr8:89,412,621–145,066,685, 872 genes, copy number 5 (broad region; genes not listed).
- chr9:92,110,575–115,744,330, 438 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:119,935,053–134,169,340, 375 genes, copy number 5 (broad region; genes not listed).
- chr9:135,604,345–138,253,217, 140 genes, copy number 5 (broad region; genes not listed).
- chr16:589,357–667,833, 7 genes, copy number 5 (within-gene range 4–5): RAB40C, WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2.
- chr18:45,034–23,982,556, 431 genes, copy number 5–6 (broad region; genes not listed).
- chr20:25,294,742–37,872,129, 273 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:43,189,998–59,516,039, 383 genes, copy number 5 (broad region; genes not listed).
- chr20:61,953,469–64,327,972, 136 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,551. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
